Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ABJH, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ABJH-TTP1-H (Primary Tumor).

Specimen(s) Received

1. Lung, HISTOLOGIC EXAMINATION – SURGICAL SPECIMEN
2. Lymph node, HISTOLOGIC EXAMINATION – SURGICAL SPECIMEN
3. Lymph node, HISTOLOGIC EXAMINATION – SURGICAL SPECIMEN

Gross Examination

1. Surgical specimen from right pulmonary bilobectomy, comprising the lower lobe, measuring 10x8x4 cm, with a perihilar tumor measuring 3 cm in diameter

Lower lobe [sic] measuring 16x10x6 cm, grossly free of neoplastic lesions, with diffuse emphysematous changes in the parenchyma

- A) tumor
- B) bronchial margin of resection (middle lobe)
- C) bronchial margin of resection (lower lobe)
- D) peribronchial lymph nodes, middle lobe
- E) peribronchial lymph nodes, lower lobe
- F) parenchyma, middle lobe
- G) parenchyma, lower lobe

ICD-0-3

adenocarcinoma, NOS 814013

Verified w/ TSS - Site: lung, middle lobe C34.2

ICD-10

C34.2

hw
2/12/16

2. Lymph nodes N1

3. Lymph nodes N2

Diagnosis

1. A) Moderately differentiated adenocarcinoma, G", with features of clear cell.
B-C) Uninvolved.
D) Atelectatic lung tissue.
E) Uninvolved.
F-G) Pulmonary emphysema.

2. Metastases in four of five lymph nodes.

3. Uninvolved

SNOMED

T-28000 M-80103 T-C4000 M-80006

1 of 2

True Copy

Diagnosis (Continued)

TNM

T1 N1 Mx G2

Addendum

G" should be GII.

HPA Discrepancy		✓

Source: NCI Genomic Data Commons file a4587d82-2e5e-4320-8843-128d4bdbe7e4 (CDDP-ABJH-TTP1.9C218549-7E53-4D84-8B1B-C68A81A882C1.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).